Surgical pathology report (de-identified scan), TCGA case TCGA-69-7761, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-7761-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] / M

SPECIMEN SUBMITTED:

Part A: 4R

Part B: #7

Part C: L4

Part D: R2

Part E: LEFT LOWER LOBE

Part F: L9

Part G: GRANULOMA CONTENT

Part H: LEVEL 12

Part I: L11

Part J: LEFT LOWER LOBE

Part K: PORTION OF 7TH RIB

Part L: LEVEL 6

Part M: LEVEL 7

Final Diagnosis

1. Lymph nodes, 4R, #7, L4, R2, L9, , level 6, level 7, excision (A-D, F, L-M) - Lymph nodes, negative for neoplasm.
2. Left lung, lower lobe, lobectomy (E) Invasive adenocarcinoma, acinar type (see comment).
- Two separate foci of atypical adenomatous hyperplasia.
- Organizing acute fibrinous pneumonia.
- Pleural fibrous adhesions
- Focal bronchiectasis with calcified and hyalinized granulomas (upper lobe).
- Peribronchial lymph nodes; negative for neoplasm
3. "Granuloma content", excision (G) - Necrotizing granulomas with calcification; negative for neoplasm (see comment).
4. Lymph nodes, level 12, L11, excision (H-I) Lymph nodes with calcified hyalinized nodules; negative for neoplasm.
5. Left lung, lower lobe, wedge excision (J) Patchy organizing fibrinous pneumonia and features of airway remodeling.
6. Portion of seventh rib, excision (K) No significant pathologic changes.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

2.

Tumor Location: Left lower lobe

Tumor Size: 4.5 x 3.2 x 3.2 cm.

Vascular Invasion: Not identified.

Lymphatic Invasion: Not identified.

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Negative

Pleura/Soft Tissue Margin: pending Movat stains; addendum report will follow.

Pathologic Stage (AJCC): Stage IB (T2a N0 MX).

Additional comments: GMS and Ziehl Neelsen stains will be performed and the results reported as an addendum.

Intraoperative Diagnosis:

A. Negative for neoplasm

B. Negative for neoplasm

C. Negative for neoplasm

D. Negative for neoplasm .

Clinical Diagnosis:

LLL NODULE

K: R/O MALIGNANCY ON PLEURAL SURFACE

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received for frozen section labeled "4R" is a segment of red tissue measuring 1.9 x 1.2 x 0.5 cm. The specimen is totally submitted for frozen section in A1.

B. Received labeled "level #7" is a segment of red tissue measuring 0.7 x 0.4 x 0.3 cm. The specimen is totally submitted for frozen section in B1.

C. Received at the frozen section desk labeled "L4" is a red segment of tissue measuring 1.3 x 0.8 x 0.7 cm. The specimen is totally submitted for frozen section in C1.

D. Received for frozen section labeled "R2" is a red segment of tissue measuring 1.3 x 0.7 x 0.5 cm. The specimen is totally submitted for frozen section in D1.

E. Received in formalin labeled "left lower lobe" is a left lower lobectomy measuring 13.5 x 12 x 10 cm, and weighing 413.2 grams with a segment of unremarkable bronchus (0.8 cm in length and 1.2 cm in diameter) and adhered parietal pleura (4.5 x 3.5 x 0.2 cm) and wedge of the upper lobe (4.5 x 2.5 x 2.3 cm). Two lesions are present within the parenchyma of the lower lobe and one lesion in the upper lobe. The large lower lobe lesion consists of an irregular tan-gray firm mass measuring 4.5 x 3.2 x 3.2 cm is present within the lung parenchyma, adjacent to the visceral pleural surface, which is puckered and adhered to the parietal pleura but does not seem to be involved. The mass is located 4.0 cm of the bronchial line of resection and 2.5 cm from the parenchymal line of resection. The smaller lower lobe lesions is an irregular tan-gray soft nodule measuring 0.5 x 0.5 x 0.4 cm, located 4.1 cm from the larger mass. The upper lobe lesion is 1.5 cm apart from the larger and 2.5 from the smaller lesions in the lower lobe respectively and consists of a tan-gray calcified nodule with central necrosis measuring 2.4 x 2.2 x 1.8 cm, located 0.3 cm from the parenchymal line of resection and 0.1 cm of the pleural surface. The remaining lung and pleura show fibrous adhesions, predominantly at the staple line of the lower lobe at the base. Multiple anthracotic hilar lymph nodes are dissected. Representative sections are submitted as follows: E1 bronchial margin, E2 vascular margin, E3-E7 largest mass (E3-E4 with visceral and parietal pleura), E8 lower lobe parenchymal margin (yellow), E9 uninvolved lung tissue between lower lobe mass and upper lobe nodules, E10 E12 upper lobe nodule after decalcification with parenchymal margin (orange), E13 uninvolved lung between largest and smallest nodules, E14 small nodule totally submitted, E15 uninvolved lung, E16 fibrous adhesions, E17 lobar lymph nodes.

F. Received in formalin labeled "L9" is an irregular shaped segment of yellow-black soft tissue measuring 0.5 x 0.2 x 0.2 cm. The segments are totally submitted in formalin in F1.

G. Received in formalin labeled "granuloma contents" is an irregular shaped segment of black-white firm tissue measuring 1.5 x 1.5 x 0.5 cm. The segment is totally submitted in formalin in G1 following decalcification.

H. Received in formalin labeled "level 12" are two irregular shaped segments of tan-black soft tissue aggregating to 2.0 x 1.0 x 0.5 cm. The segments are totally submitted in formalin in H1.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

I. Received in formalin labeled "L11" are multiple irregular segments of tan-brown, soft and calcified tissue aggregating to 5.0 x 1.5 x 0.5 cm. The segments are totally submitted in formalin in I1-I2. Please note: I2 is following light decalcification.

J. Received in formalin labeled "left lower lobe" is an irregular shaped segment of brown soft tissue measuring 4.0 x 2.5 x 0.7 cm, and weighing 5.0 grams. The pleural surface is soft and roughened. The lung parenchyma is unremarkable. Representative sections are submitted in formalin as J1-J3.

K. Received in formalin labeled "portion of 7th rib" is an unoriented segment of bone with attached soft tissue measuring 8.0 x 2.0 x 0.6 cm. Representative sections are submitted in formalin following decalcification as follows: K1 one margin, K2 opposite margin, K3-K4 additional representative sections.

L. Received in formalin labeled "level 6" are multiple irregular segments of yellow-black soft tissue aggregating to 1.0 x 0.2 x 0.2 cm. The segments are totally submitted in formalin in L1.

M. Received in formalin labeled "level 7" is an irregular shaped segment of yellow-black soft tissue measuring 0.5 x 0.2 x 0.2 cm. The specimen is totally submitted in formalin in M1.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file f6146012-c092-4ee1-a66e-2e280f7e6e51 (TCGA-69-7761.1148DAAF-0315-4639-92DD-F17FF727C6CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).